Gene-level copy-number profile of tumor specimen TCGA-CV-7416-01A from TCGA case TCGA-CV-7416, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 29.9 years (10,936 days).
Specimen TCGA-CV-7416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.49f6a606-d10b-4a7a-ab1a-05d0f8305c2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7416-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f1d8f4e-a39f-4583-8afc-ed92642ca085

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 714; copy number 2: 29,854; copy number 3: 20,025; copy number 4: 8,111; copy number 5: 39; copy number 6: 39; copy number 8: 728; copy number 9: 4; copy number 11: 45; copy number 12: 26; copy number 14: 73; copy number 22: 39; copy number 24: 9; copy number 34: 21; copy number 35: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7416-01A-11D-2077-01): tumor purity 0.62, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,007 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:10,449,820–10,779,944, 1 gene, copy number 5 (within-gene range 3–5): MGC4859.
- chr7:10,702,676–11,169,623, 6 genes, copy number 5: AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52.
- chr11:95,482,406–95,790,409, 5 genes, copy number 6 (within-gene range 4–6): AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B.
- chr13:95,677,139–98,455,176, 37 genes, copy number 11–12 (within-gene range 4–12): DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1.
- chr13:100,708,325–114,337,626, 200 genes, copy number 11–35 (within-gene range 4–35) (broad region; genes not listed).
- chr15:92,580,741–93,027,996, 19 genes, copy number 6 (within-gene range 3–6): AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175.
- chr20:30,214,765–31,259,632, 14 genes, copy number 14: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115.
- chr20:36,751,791–37,344,109, 15 genes, copy number 6: DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL, AL034422.1.

Autosomal genes at a single copy (total copy number 1): 714. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
